Gene-level copy-number profile of tumor specimen TCGA-UF-A7JO-01A from TCGA case TCGA-UF-A7JO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.3 years (28,951 days).
Specimen TCGA-UF-A7JO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.769e10af-89d2-49e0-bf80-20c8b24b1960.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A7JO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83d1b254-e221-4713-b629-0a6ef07480e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,393; copy number 2: 47,339; copy number 3: 8,948; copy number 4: 763; copy number 5: 53; copy number 7: 42; copy number 8: 77; copy number 10: 113; copy number 12: 85.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A7JO-01A-11D-A34I-01): tumor purity 0.43, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 370 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:63,844,700–74,728,851, 208 genes, copy number 8–12 (broad region; genes not listed).
- chr17:35,816,717–39,747,291, 162 genes, copy number 5–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
